CCDI case PBCJKW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f7da0fbf-01ca-4163-bc5f-7cf2204f913b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.9 years (6,901 days).

Biospecimens (3 samples)
- Sample 0DT9N3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9NG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT9NS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
